Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3725, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3725-01A (Primary Tumor).

Diagnosis/ diagnoses:

Resected rectosigmoid sample (23.5 cm in length) includes a moderately differentiated adenocarcinoma of the colorectal type, located 4 cm from the aboral resection margin, measuring a max of 3.5 cm in diameter, with widespread infiltration of the perirectal fatty tissue and with five regional lymph node metastases. Tumor-free colon resection margins. The minimum distance between the tumor and the circumferential resection margin is 1 cm. In addition, diverticulosis coli.

Stage of tumor: pT3 pN2 (5/18) pMX; G2, L1, V1, local R0.

Source: NCI Genomic Data Commons file 7d55dde5-ec48-43b7-8917-0232d14ca31d (TCGA-AG-3725.BA43BE31-01AC-4D4B-AE26-08C35FC30612.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).